TARGET case TARGET-40-NAAWFM — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms.
https://portal.gdc.cancer.gov/cases/360437de-6754-5f35-9b37-3d9d5601e682

Biospecimens (1 sample)
- Sample TARGET-40-NAAWFM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
